Gene-level copy-number profile of tumor specimen TCGA-N5-A4RF-01A from TCGA case TCGA-N5-A4RF, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Age at diagnosis: 68.6 years (25,041 days).
Specimen TCGA-N5-A4RF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 68c15f3c-bffe-4e69-98b1-be49d60692c1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-N5-A4RF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5601b6d8-d459-48de-a3fc-cb4a24aeddf4

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 27; copy number 2: 21; copy number 3: 4,641; copy number 4: 9,813; copy number 5: 24,347; copy number 6: 10,014; copy number 7: 3,715; copy number 8: 5,750; copy number 9: 18; copy number 10: 47; copy number 12: 1; copy number 15: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-N5-A4RF-01A-11D-A28Q-01): tumor purity 0.74, ploidy 5.22, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:125,734,295–125,748,098, 2 genes: OR7E53P, OR7E97P.
- chr15:23,354,748–23,367,231, 2 genes: GOLGA8S, RN7SL536P.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:128,405,269–128,564,679, 1 gene, copy number 15: LINC00824.
- chr11:68,312,591–68,449,275, 1 gene, copy number 12: LRP5.

Autosomal genes at a single copy (total copy number 1): 27. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
